Somatic mutation profile of cancer-model specimen HCM-BROD-0048-C71-85A (Adherent Cell Line, passage 10; aliquot HCM-BROD-0048-C71-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0048-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen HCM-BROD-0048-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bc02c44-3fe1-46c3-9fd2-b15cce3101d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0048-C71-10B (Blood Derived Normal), aliquot HCM-BROD-0048-C71-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e490c1af-b8a8-4f26-b2c5-c799ebcb6742

The open-access MAF lists 67 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 5, Intron 2, 3'Flank 1, Nonstop Mutation 1, RNA 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 156/327 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1057518602, COSV62574732; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C19orf84 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 193/500 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs991350322, COSV55740713, COSV55741648; called by muse, mutect2, varscan2
- C7 | c.2525C>A p.T842N | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100495489, COSV57472381; called by muse, mutect2, varscan2
- CAP1 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 152/326 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs772357523; called by muse, mutect2, varscan2
- CHRNA7 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 173/545 reads (32%) | catalogued as rs776390894; called by muse, mutect2, varscan2
- CHST1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 238/465 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1564995555, COSV57325381; called by muse, mutect2, varscan2
- DSG4 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs374710829; called by muse, mutect2, varscan2
- GALNT15 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as COSV60216487; called by muse, mutect2, varscan2
- GRIN2A | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 134/277 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753203288, COSV58025050, COSV58052595; called by muse, mutect2, varscan2
- HDAC9 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 128/566 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV67766183; called by muse, mutect2, varscan2
- IFT80 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs140972476, COSV58447811; called by muse, mutect2, varscan2
- IGHV3-74 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as rs535270321; called by muse, mutect2, varscan2
- KALRN | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 213/431 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV53762478, COSV53773546; called by muse, mutect2, varscan2
- KRT13 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1387797702, COSV55841145; called by muse, mutect2
- LAMC3 | c.3410C>T p.A1137V | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs773899562, COSV63095335; called by muse, mutect2, varscan2
- MUC12 | c.11798C>T p.T3933M (on ENST00000379442; = p.T3790M on NM_001164462.1) | Missense Mutation (SNP) | VAF 150/1929 reads (8%) | SIFT tolerated (0.11); catalogued as rs757255908; called by muse, varscan2
- NETO1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172565808, COSV100198073; called by muse, mutect2, varscan2
- OR1B1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs139740700; called by muse, mutect2
- OR9G1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 180/682 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs373762637; called by muse, varscan2
- PCLO | c.11890C>T p.R3964W | Missense Mutation (SNP) | VAF 126/515 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756155327, COSV61640264; called by muse, mutect2, varscan2
- PCLO | c.8897G>A p.R2966H | Missense Mutation (SNP) | VAF 169/754 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as rs765514605, COSV61663390; called by muse, mutect2, varscan2
- POLE | c.185G>A p.W62* | Nonsense Mutation (SNP) | VAF 107/232 reads (46%) | catalogued as rs1565981538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB3IP | c.808G>A p.E270K (on ENST00000550536 / NM_175623.4; = p.E254K on NM_022456.5) | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs760711719, COSV99922872; called by muse, mutect2, varscan2
- RSBN1 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 189/357 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1287169416; called by muse, mutect2, varscan2
- SCN5A | c.4877G>A p.R1626H (on ENST00000333535 / NM_198056.3; = p.R1625H on NM_000335.5) | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs199473283, CM004143, CM087239, COSV100350451; ClinVar: not provided / conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SERPINA6 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 127/454 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs370762935; called by muse, mutect2, varscan2
- TNFRSF10A | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 178/324 reads (55%) | catalogued as rs140805563; called by muse, mutect2, varscan2
- TRPV5 | c.2189G>T p.*730Lext*29 | Nonstop Mutation (SNP) | VAF 158/650 reads (24%) | catalogued as rs571420259, COSV99520440; called by muse, mutect2, varscan2
- WNT2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 154/620 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761310626, COSV55411711; called by muse, mutect2, varscan2
- ZBTB7C | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs761446062; called by muse, mutect2
- AVPR1A | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 174/362 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CAPN1 | c.2059+2_2059+3del p.X687_splice | Splice Site (DEL) | VAF 26/260 reads (10%) | called by mutect2, pindel
- CORO1B | c.343A>G p.N115D | Missense Mutation (SNP) | VAF 167/339 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CSNK1G1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH3 | c.12044C>T p.A4015V | Missense Mutation (SNP) | VAF 152/292 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- DPPA2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 180/339 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG4 | c.1522T>C p.S508P | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- EYS | c.3235A>G p.K1079E | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FAT2 | c.5504C>G p.S1835C | Missense Mutation (SNP) | VAF 153/299 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GRIN2D | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, varscan2
- HS6ST1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KRT33B | c.867G>C p.Q289H | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MS4A5 | c.533T>A p.L178* | Nonsense Mutation (SNP) | VAF 107/201 reads (53%) | called by muse, mutect2, varscan2
- NCAPD2 | c.2277_2278dup p.A760Gfs*22 | Frame Shift Ins (INS) | VAF 151/405 reads (37%) | called by mutect2, pindel, varscan2
- NOBOX | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PRRC2B | c.2344G>C p.A782P | Missense Mutation (SNP) | VAF 135/248 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMD11 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 276/522 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RDX | c.236A>T p.K79M | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHBDD3 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SRCIN1 | c.1103G>A p.G368E (on ENST00000621492; = p.G334E on NM_025248.3) | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD6 | c.3146G>A p.W1049* | Nonsense Mutation (SNP) | VAF 139/313 reads (44%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 188/366 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- BHLHE22 | c.429C>T p.G143= | Silent (SNP) | VAF 226/517 reads (44%) | called by muse, varscan2
- CYTIP | c.111C>T p.D37= | Silent (SNP) | VAF 119/292 reads (41%) | catalogued as rs767389855; called by muse, mutect2, varscan2
- DMBT1 | c.1947G>A p.T649= | Silent (SNP) | VAF 335/342 reads (98%) | catalogued as rs778507692, COSV57555529; called by muse, mutect2, varscan2
- FZD8 | c.123G>A p.P41= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- H2BC13 | c.33G>T p.P11= | Silent (SNP) | VAF 172/383 reads (45%) | catalogued as rs538894622, COSV62440524; called by muse, mutect2
- KLF14 | c.630G>A p.S210= | Silent (SNP) | VAF 32/1213 reads (3%) | catalogued as rs782015781, COSV60588672; called by muse, mutect2
- LOXL4 | c.1011C>T p.D337= | Silent (SNP) | VAF 266/266 reads (100%) | catalogued as COSV53258433; called by muse, mutect2, varscan2
- NPC1L1 | c.1842G>A p.T614= | Silent (SNP) | VAF 134/604 reads (22%) | catalogued as rs141472794; called by muse, varscan2
- NR1H2 | c.252C>T p.H84= | Silent (SNP) | VAF 107/387 reads (28%) | catalogued as rs763195837, COSV53800323; called by muse, mutect2, varscan2
- NUP210 | c.3585C>T p.H1195= | Silent (SNP) | VAF 109/222 reads (49%) | called by muse, mutect2, varscan2
- OR10Z1 | c.729G>A p.S243= | Silent (SNP) | VAF 197/362 reads (54%) | catalogued as rs765961650, COSV100779015; called by muse, mutect2, varscan2
- DNAJC16 | chr1:15574774 G>A | 3'Flank (SNP) | VAF 96/215 reads (45%) | called by muse, mutect2, varscan2
- EDA | c.396+15A>G | Intron (SNP) | VAF 295/295 reads (100%) | called by muse, mutect2, varscan2
- MFSD14C | n.442G>A | RNA (SNP) | VAF 150/308 reads (49%) | catalogued as COSV100924020; called by muse, mutect2, varscan2
- RAVER1 | c.1431+153G>A | Intron (SNP) | VAF 188/403 reads (47%) | called by muse, mutect2, varscan2
